Gene-level copy-number profile of specimen HCM-SANG-0286-C20-85A from HCMI case HCM-SANG-0286-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Tumor grade: G2.
Specimen HCM-SANG-0286-C20-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ec023500-4a4b-4cc3-98da-0092b22ceb2e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0286-C20-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/e7d4e7f7-08d8-4115-829d-916d2582d15c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 280; copy number 2: 28,096; copy number 3: 24,994; copy number 4: 5,529; copy number 5: 3.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:29,887,294–29,890,482, 2 genes: AL645929.1, HLA-H.
- chr6:29,906,543–29,908,645, 2 genes: DDX39BP1, MCCD1P1.
- chr6:29,934,101–29,934,286, 1 gene: HLA-U.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:29,849,550–29,885,615, 2 genes, copy number 5 (within-gene range 3–5): AL645929.2, HCP5B.
- chr21:8,680,538–8,680,934, 1 gene, copy number 5: CR381572.2.

Autosomal genes at a single copy (total copy number 1): 280. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
